Somatic mutation profile of tumor specimen TCGA-VT-AB3D-01A (aliquot TCGA-VT-AB3D-01A-12D-A417-09) from TCGA case TCGA-VT-AB3D, project TCGA-SARC (Sarcoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Undifferentiated sarcoma; Tissue or organ of origin: Connective, subcutaneous and other soft tissues of upper limb and shoulder; Age at diagnosis: 71.5 years (26,100 days).
Specimen TCGA-VT-AB3D-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 76d49ef4-d820-4cf8-ae57-0a123df64fbd.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-VT-AB3D-10A (Blood Derived Normal), aliquot TCGA-VT-AB3D-10A-01D-A41A-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/b4d77df4-cea8-4bed-81be-42debee2da42

The open-access MAF lists 45 somatic variants for this specimen: 32 protein-altering or splice-affecting, 11 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 26, Silent 11, Nonsense Mutation 4, Splice Site 2, Intron 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- A2M | c.1912G>A p.D638N | Missense Mutation (SNP) | VAF 7/75 reads (9%) | SIFT tolerated (0.09); PolyPhen benign (0.029); catalogued as COSV100588767; called by muse, mutect2
- AGAP1 | c.1249T>A p.C417S | Missense Mutation (SNP) | VAF 14/73 reads (19%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.989); catalogued as COSV100365742; called by muse, mutect2, varscan2
- ATRX | c.1051G>T p.E351* | Nonsense Mutation (SNP) | VAF 4/18 reads (22%) | catalogued as COSV64873757, COSV64875914; called by mutect2, varscan2
- BAIAP2 | c.1463A>G p.Q488R | Missense Mutation (SNP) | VAF 5/17 reads (29%) | SIFT tolerated (0.25); PolyPhen benign (0.101); catalogued as COSV100348335, COSV58335075; called by muse, mutect2, varscan2
- BEND4 | c.1579A>C p.S527R | Missense Mutation (SNP) | VAF 6/23 reads (26%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.03); catalogued as COSV101549765; called by muse, mutect2, varscan2
- BUB1B | c.2678+2T>C p.X893_splice | Splice Site (SNP) | VAF 7/36 reads (19%) | catalogued as COSV99807023; called by muse, mutect2, varscan2
- CACNA1I | c.2473G>A p.V825I | Missense Mutation (SNP) | VAF 18/53 reads (34%) | SIFT tolerated (0.08); PolyPhen benign (0.348); catalogued as rs199827082; called by muse, mutect2, varscan2
- CALN1 | c.464A>G p.N155S (on ENST00000329008 / NM_001017440.3; = p.N197S on NM_031468.4) | Missense Mutation (SNP) | VAF 4/47 reads (9%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.99); catalogued as COSV100207671, COSV61147691; called by muse, mutect2
- CNGA1 | c.337G>T p.D113Y | Missense Mutation (SNP) | VAF 20/129 reads (16%) | SIFT deleterious (0.03); PolyPhen benign (0.259); catalogued as COSV100652255; called by muse, mutect2, varscan2
- CPSF3 | c.1622A>G p.E541G | Missense Mutation (SNP) | VAF 10/106 reads (9%) | SIFT tolerated (0.14); PolyPhen benign (0.005); catalogued as COSV99432923; called by muse, mutect2
- CWH43 | c.255G>T p.Q85H | Missense Mutation (SNP) | VAF 7/58 reads (12%) | SIFT tolerated (0.08); PolyPhen benign (0.006); catalogued as COSV99893578, COSV99894338; called by muse, mutect2, varscan2
- ERGIC2 | c.971G>T p.G324V | Missense Mutation (SNP) | VAF 10/66 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100791989; called by muse, mutect2, varscan2
- FAT1 | c.4288G>T p.E1430* | Nonsense Mutation (SNP) | VAF 6/74 reads (8%) | catalogued as COSV101499164; called by muse, mutect2
- FGB | c.374A>G p.N125S | Missense Mutation (SNP) | VAF 5/42 reads (12%) | SIFT tolerated (0.46); PolyPhen benign (0); catalogued as COSV100122279; called by muse, mutect2, varscan2
- GPR22 | c.495G>T p.W165C | Missense Mutation (SNP) | VAF 5/25 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99772430; called by muse, mutect2, varscan2
- INPP4B | c.836G>T p.R279I | Missense Mutation (SNP) | VAF 14/120 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99525187; called by muse, mutect2, varscan2
- KCNJ15 | c.778G>T p.E260* | Nonsense Mutation (SNP) | VAF 3/35 reads (9%) | catalogued as COSV100154262; called by muse, mutect2
- KIF1A | c.4990G>A p.A1664T (on ENST00000320389 / NM_001379639.1; = p.A1656T on NM_004321.8 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 8/33 reads (24%) | SIFT tolerated (0.65); PolyPhen benign (0.001); catalogued as rs773017134, COSV100241427; called by muse, mutect2, varscan2
- LINGO1 | c.850C>T p.R284C | Missense Mutation (SNP) | VAF 3/41 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.753); catalogued as COSV100796425, COSV62437873; called by muse, mutect2
- MAMDC4 | c.2972G>T p.G991V (on ENST00000445819; = p.G912V on NM_206920.3) | Missense Mutation (SNP) | VAF 6/43 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as COSV99808100; called by muse, mutect2, varscan2
- MS4A12 | c.79G>T p.A27S | Missense Mutation (SNP) | VAF 19/82 reads (23%) | SIFT tolerated (0.1); PolyPhen benign (0.035); catalogued as COSV99189065, COSV99190010; called by muse, mutect2, varscan2
- PCDH15 | c.3559C>A p.P1187T | Missense Mutation (SNP) | VAF 7/64 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as rs1203212360, COSV100222583, COSV57265301; called by muse, mutect2
- RAE1 | c.838G>A p.A280T | Missense Mutation (SNP) | VAF 7/47 reads (15%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.769); catalogued as rs1384868563, COSV64798620; called by muse, mutect2, varscan2
- SAMSN1 | c.865C>T p.P289S | Missense Mutation (SNP) | VAF 8/87 reads (9%) | SIFT tolerated (0.09); PolyPhen benign (0.022); catalogued as COSV99581697; called by muse, mutect2
- SATB2 | c.526C>T p.R176C | Missense Mutation (SNP) | VAF 9/73 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs1367792848, COSV99611583; called by muse, mutect2, varscan2
- SIGLEC9 | c.152T>A p.I51N | Missense Mutation (SNP) | VAF 5/59 reads (8%) | SIFT tolerated (0.22); PolyPhen benign (0.01); catalogued as COSV99142683; called by muse, mutect2
- SMYD5 | c.955G>T p.V319L | Missense Mutation (SNP) | VAF 4/38 reads (11%) | SIFT tolerated (0.59); PolyPhen benign (0.176); catalogued as COSV99240286; called by muse, mutect2
- TCF7L2 | c.789-1G>T p.X263_splice (on ENST00000355995 / NM_001367943.1; = p.X240_splice on NM_030756.5) | Splice Site (SNP) | VAF 3/31 reads (10%) | catalogued as COSV99526105; called by muse, mutect2
- TTC22 | c.899G>A p.R300H | Missense Mutation (SNP) | VAF 4/40 reads (10%) | SIFT tolerated (0.15); PolyPhen benign (0.005); catalogued as rs145786276; called by mutect2, varscan2
- VPS13A | c.5071G>A p.D1691N | Missense Mutation (SNP) | VAF 27/120 reads (23%) | SIFT tolerated (0.58); PolyPhen benign (0.059); catalogued as rs757282617, COSV100653017, COSV62428410; called by muse, mutect2, varscan2
- ZAN | c.4870C>T p.H1624Y | Missense Mutation (SNP) | VAF 12/37 reads (32%) | SIFT deleterious (0.04); PolyPhen benign (0.09); catalogued as rs756876414, COSV100769851; called by muse, mutect2, varscan2
- SARM1 | c.589G>T p.E197* | Nonsense Mutation (SNP) | VAF 7/33 reads (21%) | called by muse, mutect2, varscan2
- GRIN2B | c.3039C>T p.T1013= | Silent (SNP) | VAF 4/34 reads (12%) | catalogued as COSV101663083; called by mutect2, varscan2
- MAST4 | c.2181C>T p.Y727= (on ENST00000403625 / NM_001164664.2; = p.Y538= on NM_015183.3) | Silent (SNP) | VAF 14/98 reads (14%) | catalogued as rs772692846, COSV99844584; called by muse, mutect2
- METTL25 | c.957T>C p.P319= | Silent (SNP) | VAF 6/87 reads (7%) | catalogued as COSV99942436; called by muse, mutect2
- OBSCN | c.4620G>A p.A1540= | Silent (SNP) | VAF 9/50 reads (18%) | catalogued as rs781225150, COSV52810164, COSV99480418; called by muse, mutect2, varscan2
- OR5P2 | c.750C>A p.T250= | Silent (SNP) | VAF 6/36 reads (17%) | catalogued as COSV100271378; called by muse, mutect2, varscan2
- PGR | c.1767C>G p.V589= | Silent (SNP) | VAF 10/102 reads (10%) | catalogued as COSV99678571; called by muse, mutect2
- RAB42 | c.87G>A p.Q29= | Silent (SNP) | VAF 7/46 reads (15%) | catalogued as COSV100866091; called by muse, mutect2
- SHARPIN | c.705G>A p.A235= | Silent (SNP) | VAF 5/38 reads (13%) | catalogued as rs778021240, COSV100010228; called by muse, mutect2, varscan2
- SHD | c.792G>T p.V264= | Silent (SNP) | VAF 3/37 reads (8%) | catalogued as COSV100010342; called by muse, mutect2
- SYT4 | c.840A>G p.R280= | Silent (SNP) | VAF 15/82 reads (18%) | catalogued as COSV99673974; called by muse, mutect2, varscan2
- TCP1 | c.1207T>C p.L403= | Silent (SNP) | VAF 3/24 reads (13%) | catalogued as rs1230490587, COSV100364948; called by muse, mutect2
- BX119917.1 | n.238G>T | RNA (SNP) | VAF 3/34 reads (9%) | called by muse, mutect2
- KLK13 | c.52+1211C>A | Intron (SNP) | VAF 6/49 reads (12%) | catalogued as rs904995706; called by muse, mutect2, varscan2
